PECGS case C083-000076 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/0b39df1d-5f17-4d79-a854-013a25866faf

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 63 years; Year of birth: 1959; Vital status: Dead; Education level: Some High School or Less.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cecum; Age at diagnosis: 63.0 years (23,011 days); AJCC clinical stage: Stage II; AJCC pathologic stage: Stage IIIC; Progression or recurrence: no.
2. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; Age at diagnosis: 63.0 years (23,011 days); AJCC clinical stage: Stage II; AJCC pathologic stage: Stage IIIC; Progression or recurrence: no.

Other clinical attributes
- Menopause status: Postmenopausal.

Biospecimens (2 samples)
- Sample C083-000076_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000076_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
